Somatic mutation profile of tumor specimen 1105249 (aliquot 7316UP-1273-1105249) from CPTAC case C224967, project CPTAC-3 (Complex Epithelial Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenosquamous carcinoma.
Specimen 1105249: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abef87ff-6318-4c1a-8701-054519473850.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105291 (Blood Derived Normal), aliquot 7316UP-743-1105291; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4133a3a-1afe-4c5a-b025-d0e3738b6b8f

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2B3 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2
